Somatic mutation profile of tumor specimen ALCH-B35I-TTP1-A (aliquot ALCH-B35I-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B35I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.5 years (20,989 days).
Specimen ALCH-B35I-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e88ee72d-4b13-485d-963e-99fde8a51f0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B35I-NB1-A (Blood Derived Normal), aliquot ALCH-B35I-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31c7af5f-946b-478b-b2ac-71dae12eece4

The open-access MAF lists 149 somatic variants for this specimen: 108 protein-altering or splice-affecting, 25 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 25, Nonsense Mutation 12, Intron 8, RNA 5, Splice Site 4, Splice Region 2, 3'UTR 1, 3'Flank 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 41/444 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.694A>T p.I232F | Missense Mutation (SNP) | VAF 22/277 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52677046, COSV52701937, COSV52704131, COSV53187960; called by muse, mutect2
- AC008397.2 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as COSV53206756; called by muse, mutect2
- ANOS1 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as COSV99390406; called by muse, mutect2
- AOAH | c.1368C>A p.V456= | Splice Region (SNP) | VAF 16/407 reads (4%) | catalogued as COSV51747125; called by muse, mutect2
- CACNB2 | c.605G>C p.G202A (on ENST00000324631 / NM_201596.3; = p.G147A on NM_000724.4) | Missense Mutation (SNP) | VAF 31/428 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV56634126; called by muse, mutect2
- CHRM3 | c.599G>T p.W200L | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55105667; called by muse, mutect2
- COL17A1 | c.3397C>A p.R1133S | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV62226680; called by muse, mutect2
- CTAGE9 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 20/697 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99040528; called by muse, mutect2
- DCAF4L2 | c.496G>C p.G166R | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV100150642; called by muse, mutect2
- F5 | c.2923C>A p.P975T | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV63125942; called by muse, mutect2
- FAM83B | c.1397C>A p.S466Y | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138195667, COSV60926717; called by muse, mutect2
- GJA4 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV60725559; called by muse, mutect2
- ICAM3 | c.1618G>C p.G540R | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1246125087; called by muse, mutect2
- IL1RAPL1 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 20/198 reads (10%) | catalogued as COSV56266184; called by muse, mutect2
- LAMA4 | c.2451G>T p.R817S (on ENST00000230538 / NM_001105206.3; = p.R810S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/566 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100038967; called by muse, mutect2
- LRRC59 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 12/194 reads (6%) | catalogued as rs754574601; called by muse, mutect2
- MKX | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV65393230; called by muse, mutect2
- MPP2 | c.541G>A p.V181M (on ENST00000461854 / NM_001278372.2; = p.V157M on NM_005374.5) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV52237005, COSV52238291; called by muse, mutect2
- MUC16 | c.28624C>A p.P9542T | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV67470790; called by muse, mutect2
- MYH4 | c.2588C>A p.T863N | Missense Mutation (SNP) | VAF 27/604 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV55127608; called by muse, mutect2
- MYSM1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 15/388 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1236428340; called by muse, mutect2
- NID1 | c.3418C>T p.Q1140* | Nonsense Mutation (SNP) | VAF 16/260 reads (6%) | catalogued as rs1313417969; called by muse, mutect2
- NUDT12 | c.1170G>A p.W390* | Nonsense Mutation (SNP) | VAF 26/282 reads (9%) | catalogued as rs370335744; called by muse, mutect2
- OTX1 | c.971C>A p.A324D | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV56994618; called by muse, mutect2
- PPP1R2B | c.563C>A p.S188* | Nonsense Mutation (SNP) | VAF 24/440 reads (5%) | catalogued as COSV70372952; called by muse, mutect2
- PXDN | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV53248532; called by muse, mutect2
- PYHIN1 | c.15C>A p.Y5* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs1368228534; called by muse, mutect2
- RP1 | c.2180G>T p.C727F | Missense Mutation (SNP) | VAF 12/405 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.24); catalogued as CX1310311; called by muse, mutect2
- SPTA1 | c.1947G>T p.E649D | Missense Mutation (SNP) | VAF 34/588 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV63755551; called by muse, mutect2
- THNSL1 | c.2027T>C p.M676T | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs910201191; called by muse, mutect2
- TSNARE1 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV56176928; called by muse, mutect2
- UPK1A | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1255185739, COSV55878035, COSV55879143; called by muse, mutect2
- ZFHX4 | c.9514C>A p.P3172T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1273442808, COSV51464433; called by muse, mutect2, varscan2
- ZNF385D | c.220C>G p.H74D | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.26); catalogued as COSV55758010; called by muse, mutect2
- AADACL2 | c.793A>G p.R265G | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.216); called by muse, mutect2
- ACE | c.2616G>T p.E872D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- AFF2 | c.2419C>A p.L807I | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANK3 | c.2575A>C p.M859L | Missense Mutation (SNP) | VAF 16/329 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- APBB3 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 31/475 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2
- ARHGAP33 | c.22A>T p.S8C | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- ATP6V0D1 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.258); called by muse, mutect2
- C11orf21 | c.9G>T p.R3S (on ENST00000381153 / NM_001329958.2; = p.G21V on NM_001142946.3) | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); called by muse, mutect2
- CACNB4 | c.148-1G>T p.X50_splice | Splice Site (SNP) | VAF 31/571 reads (5%) | called by muse, mutect2
- CCDC168 | c.13672C>A p.Q4558K | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- CENPE | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); called by muse, mutect2
- CHD6 | c.6998G>T p.G2333V | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- CHRNA9 | c.443C>A p.P148Q | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CHSY1 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 16/413 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- COL17A1 | c.4168C>A p.L1390M | Missense Mutation (SNP) | VAF 15/395 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL24A1 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2
- CSMD2 | c.5218G>T p.E1740* | Nonsense Mutation (SNP) | VAF 17/210 reads (8%) | called by muse, mutect2
- CSMD3 | c.3659T>G p.I1220S (on ENST00000297405 / NM_001363185.1; = p.I1116S on NM_052900.3) | Missense Mutation (SNP) | VAF 31/406 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- CT83 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CUBN | c.10583C>A p.P3528Q | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DAB2 | c.1248G>T p.L416F | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.341); called by muse, mutect2
- DCAKD | c.56A>T p.Q19L | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.407); called by muse, mutect2
- DENND1C | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- DNAH9 | c.1206C>A p.S402R | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- DNAI1 | c.621G>T p.R207= | Splice Region (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- DST | c.13768C>A p.P4590T (on ENST00000361203 / NM_001374722.1; = p.P2178T on NM_015548.5) | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- EBF3 | c.1105G>T p.G369C (on ENST00000355311 / NM_001375392.1; = p.G360C on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/373 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- F11 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 26/524 reads (5%) | called by muse, mutect2
- FAM161A | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 38/772 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0.264); called by muse, mutect2
- FLG2 | c.5726G>A p.G1909E | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2
- FRMD6 | c.487G>T p.D163Y (on ENST00000344768 / NM_001267046.2; = p.D155Y on NM_152330.4) | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GCKR | c.1622C>A p.A541E | Missense Mutation (SNP) | VAF 24/405 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2
- GK2 | c.394G>T p.G132* | Nonsense Mutation (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- GRM8 | c.1702G>T p.G568C | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- HECW1 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2
- HMCN1 | c.3931G>T p.E1311* | Nonsense Mutation (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- HMCN1 | c.13432C>G p.H4478D | Missense Mutation (SNP) | VAF 27/352 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.174); called by muse, mutect2
- HMX1 | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- KCNJ16 | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF2B | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2
- KIF5A | c.445+1G>T p.X149_splice | Splice Site (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- LDB3 | c.506G>T p.R169M | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LTBP1 | c.3490G>C p.E1164Q (on ENST00000404816 / NM_206943.4; = p.E838Q on NM_000627.4) | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LYNX1-SLURP2 | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MEI1 | c.87C>G p.Y29* | Nonsense Mutation (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- MXRA5 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MYL2 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 21/424 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2
- NCBP2 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- NUTM2F | c.1163A>T p.E388V | Missense Mutation (SNP) | VAF 11/277 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2
- OR4K2 | c.377T>A p.I126K | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR5L2 | c.284T>A p.L95Q | Missense Mutation (SNP) | VAF 22/327 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.66); called by muse, mutect2
- PAPPA2 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- PAX7 | c.393G>A p.W131* | Nonsense Mutation (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- PKD2L1 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.838); called by muse, mutect2
- PKLR | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 17/359 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PLEKHA4 | c.1358G>C p.G453A | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.113); called by muse, mutect2
- PLEKHM1 | c.1714A>T p.T572S | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2
- PRDM9 | c.674T>A p.V225E | Missense Mutation (SNP) | VAF 39/418 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PRR9 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.737); called by muse, mutect2
- PSG2 | c.948G>T p.L316F | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2
- RPGR | c.2340G>C p.K780N | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- RYR3 | c.14326A>G p.R4776G (on ENST00000389232; = p.R4777G on NM_001036.6) | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SENP5 | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2
- STK11 | c.675del p.N226Tfs*61 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, varscan2
- STRA6 | c.887T>A p.L296Q | Missense Mutation (SNP) | VAF 18/484 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- TENM2 | c.421A>T p.S141C | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- TMEM248 | c.897G>T p.Q299H | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- TMEM273 | c.294-1G>T p.X98_splice | Splice Site (SNP) | VAF 23/361 reads (6%) | called by muse, mutect2
- UTP25 | c.1428G>T p.E476D | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.396); called by muse, mutect2
- VAV3 | c.381-1G>T p.X127_splice | Splice Site (SNP) | VAF 22/412 reads (5%) | called by muse, mutect2
- VWF | c.3343G>T p.G1115C | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP1 | c.864A>T p.R288S | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZNF160 | c.1543G>T p.G515W | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM30 | c.915T>A p.L305= | Silent (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- ADCYAP1R1 | c.114C>A p.I38= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as rs1218036882, COSV58445493; called by muse, mutect2
- ADGRA1 | c.450G>C p.G150= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- ARFGEF2 | c.1863A>G p.T621= | Silent (SNP) | VAF 17/239 reads (7%) | catalogued as rs767517509; called by muse, mutect2
- CPS1 | c.264C>A p.A88= | Silent (SNP) | VAF 26/452 reads (6%) | called by muse, mutect2
- DIP2C | c.4218A>T p.G1406= | Silent (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- F9 | c.129G>T p.R43= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as CD125315; called by muse, mutect2, varscan2
- FMOD | c.1048C>T p.L350= | Silent (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- HTR1E | c.375C>A p.T125= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV59510091; called by muse, mutect2
- IGHE | c.1176G>T p.V392= | Silent (SNP) | VAF 11/284 reads (4%) | called by muse, mutect2
- LAMA3 | c.9807C>T p.P3269= (on ENST00000313654 / NM_198129.4; = p.P1660= on NM_000227.6) | Silent (SNP) | VAF 21/472 reads (4%) | catalogued as rs1246069606; called by muse, mutect2
- MARCHF10 | c.141C>T p.R47= | Silent (SNP) | VAF 26/434 reads (6%) | catalogued as rs745955088, COSV60889844, COSV60890476; called by muse, mutect2
- MYH4 | c.2589C>T p.T863= | Silent (SNP) | VAF 27/607 reads (4%) | called by muse, mutect2
- NETO1 | c.285G>A p.E95= | Silent (SNP) | VAF 9/230 reads (4%) | catalogued as rs929154185; called by muse, mutect2
- OR2M2 | c.672T>C p.A224= | Silent (SNP) | VAF 21/448 reads (5%) | called by muse, mutect2
- PRSS38 | c.498G>T p.V166= | Silent (SNP) | VAF 24/311 reads (8%) | catalogued as rs149920250; called by muse, mutect2
- RIMS2 | c.2922C>G p.T974= (on ENST00000666250 / NM_001348490.2; = p.T782= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 20/324 reads (6%) | catalogued as COSV51671152; called by muse, mutect2
- S100A8 | c.87C>T p.V29= | Silent (SNP) | VAF 15/270 reads (6%) | catalogued as rs961400954, COSV100907098; called by muse, mutect2
- SFXN2 | c.786G>T p.L262= | Silent (SNP) | VAF 13/195 reads (7%) | called by muse, mutect2
- SLC35G3 | c.1002G>T p.G334= | Silent (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- TAP2 | c.1845G>T p.L615= | Silent (SNP) | VAF 24/494 reads (5%) | called by muse, mutect2
- USP34 | c.8070C>T p.S2690= | Silent (SNP) | VAF 24/382 reads (6%) | catalogued as COSV68399694; called by muse, mutect2
- WDR49 | c.627T>A p.T209= (on ENST00000308378 / NM_001366158.1; = p.T550= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- ZNF492 | c.1455C>A p.A485= | Silent (SNP) | VAF 23/305 reads (8%) | called by muse, mutect2
- ZNF729 | c.3141C>T p.P1047= | Silent (SNP) | VAF 21/363 reads (6%) | called by muse, mutect2
- AC011773.3 | n.668-3656G>T | Intron (SNP) | VAF 18/300 reads (6%) | called by muse, mutect2
- ALDH6A1 | c.427+14C>T | Intron (SNP) | VAF 19/368 reads (5%) | called by muse, mutect2
- CHRD | c.252+42G>T | Intron (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- COLEC11 | c.*320A>T | 3'UTR (SNP) | VAF 9/220 reads (4%) | called by muse, mutect2
- CPED1 | c.540+3809G>T | Intron (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- HNRNPA3P1 | n.579G>T | RNA (SNP) | VAF 15/238 reads (6%) | called by muse, mutect2
- HOXA7 | chr7:27152934 C>A | 3'Flank (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- IGHV1-12 | n.101G>T | RNA (SNP) | VAF 7/151 reads (5%) | called by muse, mutect2
- LINC02210-CRHR1 | c.-493+10452G>T | Intron (SNP) | VAF 11/242 reads (5%) | called by muse, mutect2
- MOCS1 | c.124-75G>T | Intron (SNP) | VAF 26/325 reads (8%) | catalogued as rs140973917; called by muse, mutect2
- MRPL21 | c.553+20G>C | Intron (SNP) | VAF 24/298 reads (8%) | called by muse, mutect2
- OR2M1P | n.553C>A | RNA (SNP) | VAF 19/290 reads (7%) | called by muse, mutect2
- PLEKHG7 | c.507+9G>T | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- PRSS37 | c.-24C>T | 5'UTR (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- ST13P4 | n.250G>A | RNA (SNP) | VAF 28/548 reads (5%) | catalogued as rs1220663714; called by muse, mutect2
- ZBTB44-DT | n.337G>T | RNA (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
